Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U5, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U5-01A (Primary Tumor).

Neuropathology

Commentary:

Histology and morphology corresponds to astrocytoma WHO grade II.

Diagnosis:

Astrocytoma WHO grade II

CHF ICD-O-3
Astrocytoma, grade II
path 9400/3
Astrocytoma, diffuse
9400/3
Site: Brain, supratentorial
NOS 071.0
JW 7/25/13

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 884cddf8-25bc-456e-8b89-7aa86db401e7 (TCGA-S9-A6U5.0A1B0FCA-6B68-4BA3-946D-0B05A99ABEC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).